Somatic mutation profile of tumor specimen TCGA-NK-A5CR-01A (aliquot TCGA-NK-A5CR-01A-11D-A26M-08) from TCGA case TCGA-NK-A5CR, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.0 years (28,126 days).
Specimen TCGA-NK-A5CR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9e31d64-de6f-4bdf-978d-1f0d7535c29b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NK-A5CR-10A (Blood Derived Normal), aliquot TCGA-NK-A5CR-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd9c0c86-500c-4f35-b9df-c1760c8e345d

The open-access MAF lists 328 somatic variants for this specimen: 246 protein-altering or splice-affecting, 71 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 212, Silent 71, Nonsense Mutation 11, Splice Site 7, Frame Shift Del 6, Frame Shift Ins 5, RNA 5, In Frame Del 2, 3'UTR 2, Intron 2, Splice Region 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 34/55 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC090517.4 | c.1828A>T p.I610F | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.224); catalogued as COSV99975157; called by muse, mutect2, varscan2
- ACAN | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100718199; called by muse, mutect2
- ACSS3 | c.1705G>T p.G569C | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99699500; called by muse, mutect2
- ADAD1 | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99636317; called by muse, mutect2, varscan2
- AFF4 | c.2582C>T p.T861I | Missense Mutation (SNP) | VAF 54/73 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV99535433; called by muse, mutect2, varscan2
- AGFG2 | c.1171G>T p.G391W | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99499576; called by muse, mutect2
- AGTPBP1 | c.1738G>T p.V580F (on ENST00000357081 / NM_001330701.2; = p.V540F on NM_015239.2) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as COSV100430287; called by muse, mutect2, varscan2
- ANKRD30A | c.1276G>T p.V426L (on ENST00000611781; = p.V370L on NM_052997.2) | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.785); catalogued as rs375389390; called by muse, mutect2, varscan2
- ANKRD35 | c.1808A>G p.K603R | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100841865; called by muse, mutect2, varscan2
- ANO3 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as COSV99885927; called by muse, mutect2, varscan2
- AQP11 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); catalogued as COSV100547404; called by muse, mutect2, varscan2
- ARHGAP25 | c.165G>T p.K55N (on ENST00000409202 / NM_001007231.3; = p.K48N on NM_014882.3) | Missense Mutation (SNP) | VAF 94/276 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99772193; called by muse, mutect2, varscan2
- ARHGEF1 | c.111+1G>A p.X37_splice | Splice Site (SNP) | VAF 22/85 reads (26%) | catalogued as COSV100529225; called by muse, mutect2, varscan2
- ARHGEF12 | c.3886G>C p.V1296L | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV100755225; called by muse, mutect2, varscan2
- ARID2 | c.1114A>G p.M372V | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); catalogued as COSV100537089; called by muse, mutect2, varscan2
- ASB4 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1367500389, COSV99987218, COSV99987246; called by muse, mutect2, varscan2
- ASPHD2 | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as COSV99313620; called by muse, mutect2, varscan2
- ASPM | c.5602A>G p.R1868G | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV99661169; called by muse, mutect2, varscan2
- ATP11C | c.2318A>G p.N773S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.393); catalogued as COSV100558670; called by muse, mutect2, varscan2
- ATP8B3 | c.932G>T p.S311I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100035011; called by muse, mutect2, varscan2
- ATXN1 | c.343G>T p.V115L | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV99787931; called by muse, mutect2, varscan2
- AVPR1A | c.81C>A p.N27K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV100146916; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.111); catalogued as COSV57277982, COSV99958998; called by muse, mutect2, varscan2
- BTK | c.1429A>T p.M477L | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100437941; called by muse, mutect2, varscan2
- C11orf87 | c.328C>A p.R110S | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1350053389, COSV100535913; called by muse, mutect2, varscan2
- C19orf12 | c.83G>T p.G28V (on ENST00000392278 / NM_001031726.3; = p.G17V on NM_031448.6) | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV100080536; called by muse, mutect2, varscan2
- C2CD3 | c.5155+1G>A p.X1719_splice | Splice Site (SNP) | VAF 18/80 reads (23%) | catalogued as rs757691052, COSV100487475; called by muse, mutect2, varscan2
- C6orf118 | c.1276A>G p.T426A | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV57815929; called by muse, mutect2, varscan2
- C9orf131 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV100398337; called by muse, mutect2, varscan2
- CACNA1E | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100705527; called by muse, mutect2, varscan2
- CAMK1D | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.031); catalogued as COSV101123562, COSV101124005; called by muse, mutect2, varscan2
- CAPZA1 | c.569G>A p.G190D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV99583477; called by muse, mutect2, varscan2
- CCN5 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs796268795, COSV99509488; called by muse, mutect2, varscan2
- CCT8L2 | c.200C>A p.T67K | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV100743159; called by muse, mutect2, varscan2
- CDH16 | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs757524926, COSV55334704; called by muse, mutect2, varscan2
- CDHR2 | c.406-1G>A p.X136_splice | Splice Site (SNP) | VAF 17/23 reads (74%) | catalogued as COSV99992211; called by muse, mutect2, varscan2
- CEP78 | c.550A>T p.T184S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.079); catalogued as COSV99450963; called by muse, mutect2, varscan2
- CFAP92 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.935); catalogued as COSV99414965; called by muse, mutect2
- CLSTN3 | c.1324-2A>T p.X442_splice | Splice Site (SNP) | VAF 131/307 reads (43%) | catalogued as COSV99867742; called by muse, mutect2, varscan2
- CNTN6 | c.1982C>G p.T661R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100611893, COSV63172384; called by muse, mutect2, varscan2
- CPED1 | c.2201G>T p.C734F | Missense Mutation (SNP) | VAF 170/243 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100121543; called by muse, mutect2, varscan2
- CRYGA | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs766462446, COSV100378360, COSV100378675; called by muse, mutect2, varscan2
- CYP11B1 | c.544G>C p.G182R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.084); catalogued as COSV99455757; called by muse, mutect2, varscan2
- CYP27C1 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100079668; called by muse, mutect2, varscan2
- DAXX | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV99802705; called by muse, mutect2, varscan2
- DDX60 | c.3082C>G p.R1028G | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV101190682, COSV67099295; called by muse, mutect2, varscan2
- DEFB115 | c.177T>A p.C59* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV101269331; called by muse, mutect2, varscan2
- DLG1 | c.1637G>C p.R546P | Missense Mutation (SNP) | VAF 30/417 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV100016065; called by muse, mutect2
- DNAH1 | c.11525C>A p.P3842H | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV99964539; called by muse, mutect2, varscan2
- DNAH9 | c.4399G>T p.D1467Y | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV99308298; called by muse, mutect2, varscan2
- DPP10 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.75); catalogued as COSV100072126; called by muse, mutect2, varscan2
- EPHA3 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100349062; called by muse, mutect2, varscan2
- EXOC1 | c.2681A>T p.H894L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100638031; called by muse, mutect2, varscan2
- EYS | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 41/113 reads (36%) | catalogued as COSV60984192, COSV60993750; called by muse, mutect2, varscan2
- FAM135B | c.2912G>A p.G971E | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); catalogued as rs1442392631, COSV52729001; called by muse, mutect2, varscan2
- FASLG | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV100390674; called by muse, mutect2, varscan2
- FLG | c.8274C>A p.S2758R | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.396); catalogued as COSV100912265; called by muse, mutect2, varscan2
- FRMD4A | c.1978C>T p.R660C | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs376959985; called by muse, mutect2, varscan2
- FZR1 | c.1091C>G p.S364C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV100553884; called by muse, mutect2
- GABPB1 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99590143; called by muse, mutect2, varscan2
- GALNT11 | c.300G>C p.M100I | Missense Mutation (SNP) | VAF 110/165 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100232054; called by muse, mutect2, varscan2
- GIPC1 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100600161; called by muse, mutect2, varscan2
- GJA8 | c.363C>G p.N121K | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0.071); catalogued as COSV53789349, COSV99569742; called by muse, mutect2, varscan2
- GLI1 | c.2591C>A p.P864H | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV99954742; called by muse, mutect2, varscan2
- GPC3 | c.995A>T p.Q332L | Missense Mutation (SNP) | VAF 49/68 reads (72%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100893601; called by muse, mutect2, varscan2
- GRM1 | c.1073G>T p.R358M | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs112817798, COSV51110029; called by muse, mutect2, varscan2
- HAND2 | c.148C>A p.H50N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.632); catalogued as COSV100854250; called by muse, mutect2
- HECW1 | c.2332G>A p.G778R | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.561); catalogued as rs373326288, COSV101224129; called by muse, mutect2
- HERC2 | c.6787-1G>A p.X2263_splice | Splice Site (SNP) | VAF 20/48 reads (42%) | catalogued as COSV99876895; called by muse, mutect2, varscan2
- HGF | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 83/126 reads (66%) | SIFT tolerated (0.71); PolyPhen benign (0.208); catalogued as COSV55954482; called by muse, mutect2, varscan2
- HIP1 | c.2827A>C p.N943H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV100418195; called by muse, mutect2, varscan2
- HMGCR | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV99843331, COSV99843415; called by muse, mutect2
- HOXC10 | c.83G>C p.S28T | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV100329179; called by muse, mutect2, varscan2
- HPS5 | c.1006T>A p.C336S (on ENST00000349215 / NM_181507.2; = p.C222S on NM_007216.4) | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100752372; called by muse, mutect2
- HS3ST4 | c.1308C>G p.N436K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100503177; called by muse, mutect2, varscan2
- HTRA4 | c.1240A>G p.K414E | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100205971; called by muse, mutect2, varscan2
- IDO2 | c.1005G>T p.Q335H (on ENST00000389060; = p.Q348H on NM_194294.2) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100584977; called by muse, mutect2, varscan2
- IFNA6 | c.117G>T p.M39I | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV101207031; called by muse, mutect2, varscan2
- IGKV4-1 | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.091); catalogued as rs148071875; called by muse, mutect2, varscan2
- INCENP | c.874A>C p.T292P | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV99611609; called by muse, mutect2, varscan2
- INHBC | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV100548059; called by muse, mutect2, varscan2
- KCNA1 | c.525G>T p.M175I | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV66836541, COSV66836775; called by muse, mutect2, varscan2
- KCNA1 | c.526G>T p.V176F | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.199); catalogued as COSV101230374; called by muse, mutect2, varscan2
- KIAA1109 | c.3339G>A p.W1113* | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | catalogued as COSV99177299; called by mutect2, varscan2
- KIF7 | c.4007T>C p.I1336T | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747455856, COSV99180232; called by muse, mutect2, varscan2
- KLHL13 | c.1336G>T p.V446F | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99452550; called by muse, mutect2, varscan2
- KLHL4 | c.1643G>T p.R548L | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV64140218; called by muse, mutect2, varscan2
- KRT78 | c.1096C>G p.L366V | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.55); catalogued as COSV100467656, COSV58854395; called by muse, mutect2, varscan2
- KRTAP5-5 | c.92G>T p.C31F | Missense Mutation (SNP) | VAF 25/121 reads (21%) | PolyPhen benign (0.36); catalogued as rs1351969733, COSV68784973; called by muse, mutect2, varscan2
- LGALS3BP | c.1136A>T p.Q379L | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV99431949; called by muse, mutect2, varscan2
- LILRA4 | c.1304C>T p.T435I | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.372); catalogued as COSV99393405; called by muse, mutect2, varscan2
- LILRB4 | c.652T>A p.S218T | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as COSV99554136; called by muse, mutect2, varscan2
- LRCH4 | c.1179-1G>T p.X393_splice | Splice Site (SNP) | VAF 24/143 reads (17%) | catalogued as COSV59642289; called by muse, mutect2, varscan2
- LRIG1 | c.949A>G p.N317D | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99834477; called by muse, mutect2, varscan2
- LRP10 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100612518; called by muse, mutect2, varscan2
- LRRC37B | c.2423C>T p.S808F | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.953); catalogued as COSV100496547; called by muse, mutect2, varscan2
- LRRC43 | c.1684C>A p.L562I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV100148859; called by muse, mutect2, varscan2
- LRRIQ1 | c.686A>G p.Q229R | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV101277743; called by muse, mutect2, varscan2
- LRRIQ1 | c.3671A>G p.K1224R | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV67825759, COSV67827919; called by muse, mutect2, varscan2
- LRTM2 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV99766567; called by muse, mutect2, varscan2
- MAPT | c.2243C>T p.S748F (on ENST00000262410 / NM_001377265.1; = p.S356F on NM_005910.5) | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99291385; called by muse, mutect2, varscan2
- MARCO | c.565A>C p.T189P | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100503885; called by muse, mutect2, varscan2
- MATK | c.362C>A p.P121Q (on ENST00000310132 / NM_139355.3; = p.P122Q on NM_002378.4) | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs773709945, COSV59554931; called by muse, mutect2
- MBOAT2 | c.517A>C p.S173R | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100020676; called by muse, mutect2, varscan2
- MBTPS1 | c.1862A>G p.K621R | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV100597841; called by muse, mutect2, varscan2
- MED24 | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100673345; called by muse, mutect2, varscan2
- MKX | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); catalogued as COSV101008892, COSV65392201; called by muse, mutect2, varscan2
- MON2 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.95); PolyPhen benign (0.219); catalogued as COSV99743660; called by muse, mutect2
- MTX2 | c.446A>T p.Y149F | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as COSV99981434; called by muse, mutect2, varscan2
- MUC17 | c.7204G>T p.V2402L | Missense Mutation (SNP) | VAF 127/858 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV60301853; called by muse, mutect2, varscan2
- MUC17 | c.8114C>A p.A2705D | Missense Mutation (SNP) | VAF 524/754 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV100075153; called by muse, mutect2, varscan2
- MUC4 | c.15819C>A p.N5273K (on ENST00000463781 / NM_018406.7; = p.N1037K on NM_004532.6) | Missense Mutation (SNP) | VAF 49/377 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as rs773068981, COSV100206644, COSV57771389; called by muse, mutect2, varscan2
- MVP | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as rs1165016987, COSV100651751; called by muse, mutect2, varscan2
- MYB | c.1017T>A p.H339Q | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as COSV100215195, COSV57202519; called by muse, mutect2, varscan2
- MYCBP2 | c.2516-1G>T p.X839_splice (on ENST00000357337; = p.X877_splice on NM_015057.5) | Splice Site (SNP) | VAF 52/67 reads (78%) | catalogued as COSV100632007; called by muse, mutect2, varscan2
- MYF5 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209208479, COSV57355304, COSV99953423; called by muse, mutect2, varscan2
- MYH15 | c.3191T>C p.L1064P | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs1242678200, COSV99844373; called by muse, mutect2, varscan2
- MYH2 | c.371T>A p.V124D | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99821023; called by muse, mutect2, varscan2
- MYLK4 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51138398, COSV99193911; called by muse, mutect2, varscan2
- MYT1L | c.1636C>T p.L546F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101221488; called by muse, mutect2, varscan2
- NALCN | c.4602G>T p.L1534= | Splice Region (SNP) | VAF 88/132 reads (67%) | catalogued as COSV99217944; called by muse, mutect2, varscan2
- NPAP1 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100276247, COSV61506568; called by muse, mutect2, varscan2
- OAS1 | c.635T>A p.V212D | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99177293; called by muse, mutect2, varscan2
- OMG | c.1138C>A p.L380I | Missense Mutation (SNP) | VAF 95/238 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV99907947; called by muse, mutect2, varscan2
- OR10G7 | c.356A>T p.Y119F | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV100390089, COSV57866385; called by muse, mutect2
- OR10S1 | c.989C>A p.P330H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.436); catalogued as rs377386301; called by muse, mutect2, varscan2
- OR13C5 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as COSV101053183; called by muse, mutect2, varscan2
- OR1L4 | c.549G>C p.Q183H | Missense Mutation (SNP) | VAF 81/336 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.026); catalogued as COSV99413968; called by muse, mutect2, varscan2
- OR2Y1 | c.729C>A p.H243Q | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100322866; called by muse, mutect2, varscan2
- OR51D1 | c.964G>T p.G322C | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as COSV100712436; called by muse, mutect2, varscan2
- OR51D1 | c.965G>C p.G322A | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100712437; called by muse, mutect2, varscan2
- OR52J3 | c.412T>A p.L138M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100984950; called by muse, varscan2
- OR5D13 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.497); catalogued as rs1206142177, COSV100687078, COSV62334574; called by muse, mutect2, varscan2
- OR5M8 | c.212G>T p.C71F | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as COSV59117603; called by muse, mutect2, varscan2
- OR6N2 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59411349; called by muse, mutect2, varscan2
- OR8J3 | c.708dup p.A237Sfs*35 | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | catalogued as rs1214882553; called by mutect2, pindel, varscan2
- OXR1 | c.868A>G p.I290V (on ENST00000442977 / NM_001198532.1; = p.I289V on NM_018002.3) | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs765153986, COSV100367762; called by muse, mutect2
- PABPC1L | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99408216; called by muse, mutect2, varscan2
- PAMR1 | c.965G>T p.S322I (on ENST00000619888 / NM_001001991.3; = p.S339I on NM_015430.4) | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV99553345; called by muse, mutect2, varscan2
- PCDHA11 | c.828G>T p.E276D | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.02); catalogued as COSV100254853, COSV56502399; called by muse, mutect2, varscan2
- PCDHB4 | c.2030C>A p.P677Q | Missense Mutation (SNP) | VAF 74/128 reads (58%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV99522527; called by muse, mutect2, varscan2
- PCDHGB6 | c.2099C>G p.S700* | Nonsense Mutation (SNP) | VAF 51/87 reads (59%) | catalogued as COSV99547560; called by muse, mutect2, varscan2
- PCNX4 | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100470847; called by muse, mutect2, varscan2
- PDE11A | c.2609T>A p.L870Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99615175; called by muse, mutect2, varscan2
- PDPK1 | c.1554G>A p.T518= | Splice Region (SNP) | VAF 24/79 reads (30%) | catalogued as rs751320393, COSV99239563; called by muse, mutect2, varscan2
- PDZD2 | c.2612A>G p.H871R | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV99226819; called by muse, mutect2, varscan2
- PHKB | c.2206_2207insA p.C736* | Nonsense Mutation (INS) | VAF 18/41 reads (44%) | catalogued as COSV100068605; called by mutect2, pindel, varscan2
- PICALM | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100708287, COSV62670825; called by muse, mutect2, varscan2
- PLAG1 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367971972, COSV100388042; called by mutect2, varscan2
- PLD3 | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as rs1265897770, COSV99397101; called by muse, mutect2, varscan2
- PLEKHA5 | c.772T>A p.L258M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as COSV100164787; called by muse, mutect2, varscan2
- PLEKHG1 | c.746T>G p.V249G | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100651904; called by muse, mutect2, varscan2
- PLVAP | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99391845; called by muse, mutect2, varscan2
- PLXNA4 | c.2489G>T p.G830V | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.143); catalogued as COSV100327309; called by muse, mutect2, varscan2
- PLXNA4 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 56/78 reads (72%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100327315; called by muse, mutect2, varscan2
- PNPLA6 | c.4010G>T p.G1337V (on ENST00000414982 / NM_001166111.2; = p.G1289V on NM_006702.5) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.808); catalogued as COSV99654572; called by muse, mutect2, varscan2
- POFUT1 | c.593A>G p.Q198R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.46); catalogued as rs949920379, COSV101003383; called by muse, mutect2, varscan2
- POLB | c.840G>C p.K280N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV99613505; called by muse, mutect2, varscan2
- PPFIBP2 | c.2383G>C p.E795Q | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV100207052; called by muse, mutect2, varscan2
- PPP2R2C | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 74/107 reads (69%) | catalogued as COSV100067351, COSV58674619; called by muse, mutect2, varscan2
- PRAG1 | c.3412G>T p.E1138* | Nonsense Mutation (SNP) | VAF 98/169 reads (58%) | catalogued as COSV100422876; called by muse, mutect2, varscan2
- PRTG | c.718G>T p.G240C | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV101221497; called by muse, mutect2, varscan2
- PSG2 | c.770T>A p.L257H | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100283731; called by muse, mutect2, varscan2
- PTCH2 | c.2989G>C p.A997P | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as rs1173495557, COSV100942286; called by muse, mutect2, varscan2
- PTPN5 | c.1405C>A p.P469T | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs900386181, COSV100080455; called by muse, mutect2, varscan2
- RANBP6 | c.307C>A p.L103M | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as rs1242854805, COSV52388860, COSV99424441; called by muse, varscan2
- RECK | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as COSV100937675, COSV65034754; called by muse, mutect2, varscan2
- RERG | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV57005681, COSV99917609; called by muse, mutect2, varscan2
- RHBDF2 | c.1273A>G p.I425V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1161604657, COSV99166272; called by muse, mutect2, varscan2
- RIOX2 | c.227A>T p.Y76F | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as rs533721104, COSV100328624; called by muse, mutect2, varscan2
- RIPK2 | c.1135G>T p.D379Y | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV99610143; called by muse, mutect2, varscan2
- ROBO4 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1191229967, COSV100127880; called by muse, mutect2, varscan2
- RREB1 | c.4379G>T p.G1460V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV100619880; called by muse, mutect2
- SACS | c.1527C>G p.I509M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV101207749; called by muse, mutect2, varscan2
- SAMD9 | c.3499C>G p.Q1167E | Missense Mutation (SNP) | VAF 173/272 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66077125; called by muse, mutect2, varscan2
- SCN3A | c.4755C>A p.F1585L | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99328627; called by muse, mutect2, varscan2
- SETX | c.2084A>G p.N695S | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99811055; called by muse, mutect2, varscan2
- SHANK1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV99520407; called by muse, mutect2, varscan2
- SLC6A19 | c.1871C>T p.S624F | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV57250804; called by muse, mutect2, varscan2
- SMURF2 | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99301095; called by muse, mutect2, varscan2
- SPAG4 | c.775T>A p.Y259N | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100958357; called by muse, mutect2, varscan2
- SPATA18 | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as rs80047767, COSV54646538; called by muse, mutect2, varscan2
- SPTA1 | c.2762T>C p.I921T | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV100935624; called by muse, mutect2, varscan2
- SRGAP1 | c.1654G>C p.D552H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV100755171; called by muse, mutect2, varscan2
- STRN | c.1603G>A p.G535S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV99815728; called by muse, mutect2
- STT3A | c.885T>G p.F295L | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as COSV101205296; called by muse, mutect2, varscan2
- SUN5 | c.678G>T p.W226C | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100644920; called by muse, mutect2, varscan2
- SUN5 | c.677G>A p.W226* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | catalogued as COSV62182032, COSV62182453; called by muse, mutect2, varscan2
- SVEP1 | c.1084T>A p.C362S | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100239154; called by muse, mutect2, varscan2
- SYNGAP1 | c.215G>C p.R72P | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.453); catalogued as COSV99539043, COSV99539400; called by muse, mutect2, varscan2
- TAF3 | c.683T>G p.L228R | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV100720521; called by muse, mutect2, varscan2
- TAS2R7 | c.956G>C p.*319Sext*7 | Nonstop Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99554000; called by muse, mutect2, varscan2
- TBRG4 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs748231648, COSV99345687; called by muse, mutect2, varscan2
- TEAD1 | c.109C>A p.P37T | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100532946; called by muse, mutect2, varscan2
- TMCC3 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.936); catalogued as rs754506517, COSV54152328, COSV54152433; called by muse, mutect2, varscan2
- TMEM131 | c.3509A>T p.D1170V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99489663; called by muse, mutect2, varscan2
- TMEM165 | c.493G>T p.V165L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV101189686; called by muse, mutect2, varscan2
- TMEM267 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764259047, COSV101231046; called by muse, mutect2, varscan2
- TMPRSS11F | c.775T>C p.W259R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100678834; called by muse, varscan2
- TNRC6A | c.5440C>T p.L1814F | Missense Mutation (SNP) | VAF 72/114 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100170502; called by muse, mutect2, varscan2
- TRIM63 | c.352A>T p.S118C | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV100958201; called by muse, mutect2, varscan2
- TRIP12 | c.3085A>G p.K1029E | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.931); catalogued as COSV52259585; called by muse, mutect2, varscan2
- TSHZ3 | c.1276G>C p.V426L | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99552856; called by muse, mutect2, varscan2
- TTC24 | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as COSV100964373; called by muse, mutect2, varscan2
- TTK | c.2054G>T p.G685V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100036622, COSV57886829; called by muse, mutect2, varscan2
- TTLL10 | c.1341C>G p.I447M (on ENST00000379289 / NM_001130045.2; = p.I374M on NM_153254.3) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV101016945; called by muse, mutect2, varscan2
- TTN | c.69179G>C p.R23060T (on ENST00000591111; = p.R15636T on NM_003319.4) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | PolyPhen probably damaging (0.996); catalogued as COSV100631449; called by muse, mutect2, varscan2
- TTN | c.8103A>T p.K2701N (on ENST00000591111; = p.K2655N on NM_003319.4) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | PolyPhen benign (0.003); catalogued as rs750526009, COSV100631456; called by muse, mutect2, varscan2
- TULP4 | c.4318G>A p.G1440S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs374975930; called by muse, mutect2, varscan2
- USP4 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.902); catalogued as COSV99649282, COSV99649803; called by muse, mutect2, varscan2
- VIPR1 | c.226A>T p.T76S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.114); catalogued as COSV100285772; called by muse, mutect2, varscan2
- VPS13C | c.5776T>A p.S1926T (on ENST00000644861 / NM_020821.3; = p.S1883T on NM_017684.5) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99830327; called by muse, mutect2, varscan2
- WASHC3 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as COSV99527644; called by muse, mutect2, varscan2
- WASHC5 | c.778G>T p.V260L | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100573105; called by muse, mutect2, varscan2
- WEE2 | c.893A>G p.Q298R | Missense Mutation (SNP) | VAF 19/231 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as COSV101187693; called by muse, mutect2
- XRN2 | c.878G>T p.S293I | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV101018659; called by muse, mutect2, varscan2
- ZC3H7B | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV100687824; called by muse, mutect2
- ZDBF2 | c.6707A>G p.H2236R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100985581; called by muse, mutect2, varscan2
- ZFAT | c.1258G>T p.D420Y | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100914978; called by muse, mutect2, varscan2
- ZNF14 | c.926G>A p.C309Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100694147; called by muse, mutect2, varscan2
- ZNF154 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV101377549; called by muse, mutect2, varscan2
- ZNF248 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100627758; called by muse, mutect2, varscan2
- ZNF350 | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as rs780033650, COSV99702724; called by muse, mutect2, varscan2
- ZNF407 | c.862C>A p.P288T | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as COSV99996843; called by muse, mutect2, varscan2
- ZNF510 | c.1248A>T p.K416N | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.254); catalogued as COSV99793968; called by muse, mutect2, varscan2
- ZNF530 | c.428A>G p.E143G | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as COSV100252766; called by muse, mutect2, varscan2
- ZNF536 | c.1078C>A p.L360I | Missense Mutation (SNP) | VAF 120/271 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100835995; called by muse, mutect2, varscan2
- ZNF543 | c.1719G>A p.M573I | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs767098879, COSV100386947; called by muse, mutect2, varscan2
- ZNF559 | c.488T>A p.V163D | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.2); catalogued as COSV100416770; called by muse, mutect2, varscan2
- ZNF566 | c.21G>T p.M7I | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs1314669463, COSV101091621, COSV67574475; called by muse, mutect2, varscan2
- ZNF799 | c.1729G>A p.G577R | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.072); catalogued as COSV101345298; called by muse, mutect2, varscan2
- ZNF831 | c.1340C>A p.T447N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1178207579, COSV100925742; called by muse, mutect2, varscan2
- ABCA4 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- AMY2A | c.176_210del p.P59Qfs*11 | Frame Shift Del (DEL) | VAF 16/99 reads (16%) | called by mutect2, pindel
- B3GAT1 | c.130dup p.R44Pfs*17 | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- CAPZA3 | c.219del p.H74Tfs*4 | Frame Shift Del (DEL) | VAF 21/83 reads (25%) | called by mutect2, pindel, varscan2
- DENND2D | c.108dup p.E37Rfs*19 | Frame Shift Ins (INS) | VAF 44/134 reads (33%) | called by mutect2, pindel, varscan2
- ERICH3 | c.3357_3358insC p.N1120Qfs*2 | Frame Shift Ins (INS) | VAF 29/86 reads (34%) | called by pindel, varscan2
- GNG2 | c.148del p.L50Sfs*2 | Frame Shift Del (DEL) | VAF 22/192 reads (11%) | called by mutect2, pindel, varscan2
- MGAM | c.4949_4950del p.I1650Rfs*19 | Frame Shift Del (DEL) | VAF 12/104 reads (12%) | called by mutect2, pindel, varscan2
- NACC1 | c.125_126del p.K42Sfs*115 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | called by mutect2, pindel, varscan2
- NFE2L2 | c.114_134del p.D38_K44del | In Frame Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel
- OR52E8 | c.787dup p.S263Ffs*10 | Frame Shift Ins (INS) | VAF 36/75 reads (48%) | called by mutect2, varscan2
- SIK2 | c.2665_2667del p.Q889del | In Frame Del (DEL) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- SRGAP1 | c.2831_2844del p.Y944* | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- ACTRT1 | c.981C>A p.P327= | Silent (SNP) | VAF 41/58 reads (71%) | catalogued as COSV100947767; called by muse, mutect2, varscan2
- ADAMTS15 | c.1782C>G p.T594= | Silent (SNP) | VAF 33/178 reads (19%) | catalogued as COSV100143806; called by muse, mutect2, varscan2
- ANGPTL6 | c.996A>G p.E332= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99464002; called by muse, mutect2, varscan2
- ANKRD44 | c.597G>T p.V199= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as COSV99986071; called by muse, mutect2, varscan2
- ANO5 | c.1797A>G p.E599= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV100202257; called by muse, mutect2, varscan2
- ATF7IP | c.117T>A p.T39= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV99662149; called by muse, mutect2, varscan2
- BSN | c.10014C>T p.P3338= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as rs866608898, COSV99609915; called by muse, mutect2, varscan2
- C3orf33 | c.795T>C p.Y265= (on ENST00000340171 / NM_001308229.2; = p.Y222= on NM_173657.2) | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1329402938, COSV100420174; called by muse, mutect2
- CACNA1E | c.564C>A p.T188= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100705525, COSV62382623; called by muse, mutect2, varscan2
- CACNA1S | c.1032C>G p.A344= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV100755401; called by muse, mutect2
- CELSR1 | c.4794A>G p.L1598= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV99420145; called by muse, mutect2, varscan2
- CHRM1 | c.702G>A p.G234= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100186306; called by muse, mutect2, varscan2
- CILP | c.1170C>A p.A390= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99973972; called by muse, mutect2, varscan2
- CTPS1 | c.897C>T p.C299= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV101009424; called by muse, mutect2, varscan2
- CYP4F3 | c.1386A>G p.S462= | Silent (SNP) | VAF 74/165 reads (45%) | catalogued as rs369596115; called by muse, mutect2
- DNAH9 | c.4398G>A p.E1466= | Silent (SNP) | VAF 36/59 reads (61%) | catalogued as rs1308658218, COSV99308296; called by muse, mutect2, varscan2
- DOCK2 | c.5398C>A p.R1800= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV99915663; called by muse, mutect2, varscan2
- EGR4 | c.726G>T p.P242= (on ENST00000545030; = p.P139= on NM_001965.4) | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV101474265; called by muse, mutect2, varscan2
- ELAVL2 | c.688C>T p.L230= | Silent (SNP) | VAF 87/152 reads (57%) | catalogued as COSV99807302; called by muse, mutect2, varscan2
- EWSR1 | c.99C>T p.T33= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV99328632; called by muse, mutect2, varscan2
- GMFG | c.318G>T p.G106= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV99453518; called by muse, mutect2, varscan2
- GRIN3A | c.285A>G p.A95= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100701866; called by muse, mutect2
- H2AC8 | c.105C>T p.L35= | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as rs753800823, COSV99773410; called by muse, mutect2, varscan2
- HIP1 | c.2826G>T p.V942= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100418197; called by muse, mutect2, varscan2
- IGKV4-1 | c.93G>C p.L31= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as rs552609031; called by muse, mutect2, varscan2
- INPP4B | c.510A>G p.S170= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV99526977; called by muse, mutect2
- LDLRAD3 | c.750G>T p.A250= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV100215313; called by muse, mutect2, varscan2
- LGI4 | c.744C>T p.L248= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as COSV100033003; called by muse, mutect2, varscan2
- LRIT2 | c.684C>T p.Y228= | Silent (SNP) | VAF 31/55 reads (56%) | catalogued as rs372112496, COSV100259398; called by muse, varscan2
- LRP1 | c.12376C>T p.L4126= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV99677319; called by muse, varscan2
- LRRTM4 | c.1683C>A p.P561= | Silent (SNP) | VAF 53/151 reads (35%) | catalogued as COSV101299399; called by muse, mutect2, varscan2
- MAGEL2 | c.3568C>T p.L1190= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100046241; called by muse, mutect2, varscan2
- MMRN1 | c.2529T>C p.H843= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs762146469, COSV99307803; called by muse, varscan2
- MROH5 | c.2451C>T p.F817= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV101436152, COSV71302122; called by muse, mutect2, varscan2
- MUC16 | c.42468G>C p.G14156= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV66693472; called by muse, mutect2, varscan2
- MYH13 | c.150C>A p.G50= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99355556; called by muse, mutect2
- MYH8 | c.492C>T p.A164= | Silent (SNP) | VAF 84/138 reads (61%) | catalogued as rs1469299416, COSV101238854; called by muse, mutect2, varscan2
- NETO1 | c.624A>T p.A208= | Silent (SNP) | VAF 53/135 reads (39%) | catalogued as COSV100199808; called by muse, mutect2, varscan2
- NOXA1 | c.684G>C p.A228= | Silent (SNP) | VAF 44/138 reads (32%) | catalogued as COSV100395738, COSV58162408; called by muse, mutect2, varscan2
- OR10G9 | c.27G>A p.A9= | Silent (SNP) | VAF 45/156 reads (29%) | catalogued as rs867540206, COSV66685711, COSV66686185; called by muse, mutect2, varscan2
- OR10G9 | c.663C>A p.V221= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs1276541305, COSV100901769; called by muse, mutect2, varscan2
- OR2T4 | c.610C>A p.R204= | Silent (SNP) | VAF 53/95 reads (56%) | catalogued as COSV63544206, COSV63544524; called by muse, mutect2, varscan2
- OR4C16 | c.66G>A p.K22= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs780850295, COSV58942099, COSV58943641; called by muse, mutect2
- OR4C46 | c.297C>A p.V99= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as COSV60221647; called by muse, mutect2, varscan2
- OR4F6 | c.423C>T p.C141= | Silent (SNP) | VAF 62/174 reads (36%) | catalogued as COSV100187008; called by muse, mutect2, varscan2
- OR52E4 | c.369C>T p.D123= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs748018401, COSV100389391; called by muse, mutect2, varscan2
- PIK3CG | c.3156G>T p.R1052= | Silent (SNP) | VAF 51/217 reads (24%) | catalogued as COSV100783220; called by muse, mutect2, varscan2
- POTEF | c.2097C>A p.L699= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as COSV100665374; called by muse, mutect2, varscan2
- PTCHD3 | c.1839C>A p.I613= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV101438973, COSV71256921; called by muse, mutect2, varscan2
- PTPRD | c.969C>G p.P323= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV100647211; called by muse, mutect2, varscan2
- PZP | c.3390C>T p.A1130= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV54371953; called by muse, mutect2, varscan2
- RBAK | c.456T>C p.S152= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100806785; called by muse, mutect2
- RIMBP2 | c.2550C>T p.A850= | Silent (SNP) | VAF 50/108 reads (46%) | catalogued as rs1010886650, COSV99900626; called by muse, mutect2, varscan2
- RXRA | c.267T>C p.T89= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV100709380; called by muse, mutect2, varscan2
- SAMD9L | c.1932C>T p.I644= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as COSV100561162; called by muse, mutect2, varscan2
- SIGLEC14 | c.999C>T p.I333= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as COSV55778669; called by muse, mutect2, varscan2
- SLC2A3 | c.306C>T p.V102= | Silent (SNP) | VAF 44/99 reads (44%) | catalogued as COSV99306982; called by muse, mutect2, varscan2
- SLC35C2 | c.138C>T p.L46= | Silent (SNP) | VAF 41/83 reads (49%) | catalogued as rs748412195, COSV99709609; called by muse, mutect2, varscan2
- SNTG1 | c.129G>T p.V43= | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as COSV99386342; called by muse, mutect2, varscan2
- SP140 | c.867A>G p.Q289= | Silent (SNP) | VAF 36/61 reads (59%) | catalogued as COSV100614119; called by muse, mutect2, varscan2
- SPATA16 | c.1161G>T p.G387= | Silent (SNP) | VAF 163/196 reads (83%) | catalogued as COSV63533982; called by muse, mutect2, varscan2
- SPTA1 | c.840C>T p.I280= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV100935625; called by muse, mutect2, varscan2
- TBCB | c.717C>T p.Y239= | Silent (SNP) | VAF 67/170 reads (39%) | catalogued as rs763191211, COSV99696421; called by muse, mutect2, varscan2
- TBX3 | c.795T>C p.Y265= (on ENST00000257566 / NM_016569.4; = p.Y245= on NM_005996.4) | Silent (SNP) | VAF 45/154 reads (29%) | catalogued as rs760941951, COSV99984133; called by muse, mutect2, varscan2
- TIMM50 | c.663C>T p.D221= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs1303238327, COSV100068093; called by muse, mutect2, varscan2
- TNIP3 | c.531C>A p.S177= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV50246506, COSV99284848; called by muse, mutect2, varscan2
- TOP2B | c.162G>T p.V54= (on ENST00000264331 / NM_001330700.2; = p.V49= on NM_001068.3) | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as COSV99980379; called by muse, mutect2, varscan2
- TRIM42 | c.1560C>G p.V520= | Silent (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- TRPA1 | c.1239G>C p.G413= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100085278; called by muse, mutect2
- WDR49 | c.1404A>C p.I468= (on ENST00000308378 / NM_001366158.1; = p.I809= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/258 reads (7%) | catalogued as COSV100393942, COSV57718620; called by muse, mutect2
- ZDHHC6 | c.1017C>T p.F339= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1268680046, COSV100634819; called by muse, mutect2, varscan2
- CAMK1D | c.1039+37A>T | Intron (SNP) | VAF 41/130 reads (32%) | catalogued as COSV101124004; called by muse, mutect2, varscan2
- CHCHD2P9 | n.191C>A | RNA (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- DCHS2 | n.4832C>A | RNA (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100601564; called by muse, mutect2, varscan2
- KIRREL2 | c.*32C>T | 3'UTR (SNP) | VAF 47/87 reads (54%) | catalogued as COSV99384480; called by muse, mutect2, varscan2
- MIR147A | n.31C>T | RNA (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791761 C>A | 3'Flank (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2
- SNORD116-6 | n.16C>A | RNA (SNP) | VAF 19/96 reads (20%) | called by muse, mutect2, varscan2
- SSTR3 | c.-1C>T | 5'UTR (SNP) | VAF 19/37 reads (51%) | catalogued as COSV100142908; called by muse, mutect2, varscan2
- SYTL2 | c.1459+1792A>C | Intron (SNP) | VAF 29/69 reads (42%) | catalogued as COSV100315024; called by muse, mutect2, varscan2
- TUBB7P | n.793T>A | RNA (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- UVSSA | c.*8709C>A | 3'UTR (SNP) | VAF 313/516 reads (61%) | catalogued as COSV100246351; called by muse, mutect2, varscan2
